Surgical pathology report (de-identified scan), TCGA case TCGA-DM-A282, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University Of Michigan, specimen TCGA-DM-A282-01A (Primary Tumor).

Path (First Tumor)

Tumor Site:	Hepatic Flexure Proximal
Date of Cancer Sample Procurement:	
Histology:	Adenocarcinoma
Description of other histology:	
Grade:	Well Differentiated
Mucinous:	☐ No ☐ Yes ☒ Yes (Focal) ☐ Unknown
Signet Ring Feature:	☒ No ☐ Yes ☐ Yes (Focal) ☐ Unknown
Histologic Heterogeneity:	☒ No ☐ Yes ☐ Unknown
Host Response:	Lymphoid Aggregates
Crohn's like reaction	☐ None ☒ Yes ☐ Unknown
Plasma cell rich stroma	☐ No ☐ Yes ☐ Unknown
Growth Pattern:	☒ Expansile ☐ Invasive ☐ Expansile and Invasive ☐ Unknown
Inflammatory Bowel Disease	☒ No ☐ Yes ☐ Unknown
Angiolymphatic Invasion:	☒ No ☐ Yes ☐ Unknown
Mutator Phenotype:	☒ No ☐ Yes ☐ Unknown
Number of Slides	1
Garland Necrosis present:	☐ No ☒ Yes ☐ Yes (Focal) ☐ Unknown
TIL Cells / HPF	2
Pathologist Comment:	

ICD-O-3

adenocarcinoma, mucinous, NOS 8480/3

Site: hepatic flexure C18.3

for 5/3/11

Source: NCI Genomic Data Commons file b9475d9b-c8f8-49aa-b461-083c2606254f (TCGA-DM-A282.F38C6493-9B5D-4BEC-81AB-B79CF6BD89A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).